CCDI case PBBXGE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/1c47b7ee-c43a-4242-b066-82020968f246

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 18.9 years (6,888 days).

Biospecimens (2 samples)
- Sample 0DKF9L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKFA0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
